Somatic mutation profile of tumor specimen C3N-02090-03 (aliquot CPT0118400006) from CPTAC case C3N-02090, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 61.4 years (22,432 days).
Specimen C3N-02090-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb250d7e-de98-47fd-81ff-d434b566d601.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02090-31 (Blood Derived Normal), aliquot CPT0119630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/830961a5-bf4f-4907-832e-766ed6dfb0dd

The open-access MAF lists 73 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 14, Splice Site 5, Intron 5, RNA 3, Nonsense Mutation 2, 3'UTR 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 12/111 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 36/225 reads (16%) | hotspot (GDC flag); catalogued as rs786204864, CM142087, HM971504, COSV64288951, COSV64296078, COSV64302138; ClinVar: pathogenic; called by muse, varscan2
- C12orf4 | c.1276A>G p.I426V | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs942476990; called by muse, mutect2
- CHD1L | c.1145A>G p.Y382C | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417513790; called by muse, mutect2, varscan2
- FGF4 | c.307C>A p.R103S | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as rs1401762674, COSV51449666; called by muse, mutect2, varscan2
- LILRB4 | c.1220C>A p.A407D (on ENST00000391733 / NM_001278428.3; = p.A406D on NM_001278426.3) | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs566109967; called by muse, varscan2
- MXRA5 | c.6853G>T p.V2285L | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV54248231; called by muse, mutect2, varscan2
- SIVA1 | c.8A>G p.K3R | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs777161842; called by muse, mutect2, varscan2
- SSB | c.1124A>C p.E375A | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1201618687; called by muse, mutect2, varscan2
- TFCP2 | c.1481A>G p.N494S | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as rs375189420; called by muse, mutect2
- TICRR | c.4738C>T p.P1580S | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs771243408, COSV51545795; called by muse, mutect2
- ZNF720 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs200188927; called by muse, varscan2
- ABCC1 | c.254G>T p.C85F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AVL9 | c.1220A>G p.Y407C | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, varscan2
- C10orf99 | c.105G>T p.R35S | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CA8 | c.577-1G>T p.X193_splice | Splice Site (SNP) | VAF 22/186 reads (12%) | called by mutect2, varscan2
- CDKN2B | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYS | c.6022C>G p.P2008A | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GABBR1 | c.794T>A p.L265H | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- GIPC2 | c.796+1G>A p.X266_splice | Splice Site (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
- HOXA13 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- LIPC | c.273G>T p.S91= | Splice Region (SNP) | VAF 33/253 reads (13%) | called by muse, mutect2, varscan2
- LMO7 | c.4253A>G p.N1418S (on ENST00000357063; = p.N1099S on NM_005358.5) | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.044); called by muse, mutect2
- LRRK2 | c.2794C>T p.H932Y | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- LRRN4 | c.2048T>G p.L683R | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- MAN2A2 | c.1387A>T p.T463S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAPK10 | c.624A>G p.I208M (on ENST00000359221 / NM_001351625.2; = p.I246M on NM_002753.5) | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MARS1 | c.2033del p.D678Vfs*44 | Frame Shift Del (DEL) | VAF 22/206 reads (11%) | called by pindel, varscan2
- MASP1 | c.1435C>T p.L479F | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MED12 | c.2542-25_2542-2del p.X848_splice | Splice Site (DEL) | VAF 30/193 reads (16%) | called by mutect2, pindel, varscan2
- MUC22 | c.2443A>G p.M815V | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- MUC5B | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2
- MYC | c.1136A>T p.D379V (on ENST00000377970; = p.D394V on NM_002467.6) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH1 | c.533+2T>A p.X178_splice | Splice Site (SNP) | VAF 12/104 reads (12%) | called by muse, varscan2
- MYH3 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 44/388 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MYO16 | c.4255G>A p.A1419T | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MYO18B | c.2672T>A p.L891H | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- NYNRIN | c.3770G>T p.R1257L | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR2T4 | c.1015G>C p.V339L | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDLIM5 | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PEX16 | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- RAB32 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 26/269 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2
- RGS4 | c.442T>C p.C148R | Missense Mutation (SNP) | VAF 22/299 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SYNJ1 | c.4673A>T p.N1558I | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TDRD7 | c.1511A>G p.K504R | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TOP3A | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 27/300 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- TSR1 | c.1376A>T p.Y459F | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- UBE4B | c.3170A>G p.N1057S (on ENST00000343090 / NM_001105562.3; = p.N928S on NM_006048.5) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZC3H6 | c.1419T>G p.Y473* | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
- ZC3H7B | c.1459+2T>C p.X487_splice | Splice Site (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- AKTIP | c.567T>C p.D189= | Silent (SNP) | VAF 26/194 reads (13%) | catalogued as rs1380966507; called by muse, mutect2, varscan2
- ALKBH3 | c.750G>A p.A250= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as rs758142104, COSV100236329, COSV57023668; called by muse, mutect2, varscan2
- CEP131 | c.2784C>T p.R928= (on ENST00000269392 / NM_001319228.2; = p.R925= on NM_014984.4) | Silent (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- CPEB2 | c.1881A>G p.K627= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as rs1560213405; called by muse, mutect2
- CSMD3 | c.8628T>C p.G2876= (on ENST00000297405 / NM_001363185.1; = p.G2707= on NM_052900.3) | Silent (SNP) | VAF 47/328 reads (14%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.9750G>A p.Q3250= | Silent (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- FARP2 | c.2028G>A p.T676= | Silent (SNP) | VAF 47/390 reads (12%) | catalogued as rs147634480, COSV50874927; called by muse, mutect2, varscan2
- GLP1R | c.717C>A p.A239= | Silent (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- HAS1 | c.228G>A p.L76= | Silent (SNP) | VAF 30/205 reads (15%) | called by muse, mutect2, varscan2
- PABPC4 | c.189C>T p.A63= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- SNAP23 | c.342A>T p.V114= | Silent (SNP) | VAF 30/203 reads (15%) | called by muse, mutect2, varscan2
- SOWAHA | c.24C>T p.A8= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- TSPYL6 | c.522G>A p.A174= | Silent (SNP) | VAF 46/279 reads (16%) | catalogued as rs1242105090, COSV57817835; called by muse, mutect2, varscan2
- ZNF761 | c.1287G>T p.R429= | Silent (SNP) | VAF 43/307 reads (14%) | called by muse, mutect2, varscan2
- EIF4G2 | c.1413+120C>G | Intron (SNP) | VAF 10/93 reads (11%) | catalogued as COSV100379366; called by muse, mutect2, varscan2
- FAM90A27P | n.400A>G | RNA (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2
- LRRC18 | c.*21G>T | 3'UTR (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- MPV17 | c.279+20G>A | Intron (SNP) | VAF 60/565 reads (11%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.899A>T | RNA (SNP) | VAF 30/218 reads (14%) | called by muse, mutect2, varscan2
- PTPN18 | c.93+404G>A | Intron (SNP) | VAF 15/133 reads (11%) | called by muse, mutect2, varscan2
- TMEM33 | c.328+410A>T | Intron (SNP) | VAF 20/166 reads (12%) | called by muse, varscan2
- TUBBP5 | n.1178del | RNA (DEL) | VAF 38/380 reads (10%) | called by pindel, varscan2
- TYMP | c.1160-50G>A | Intron (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
